TARGET case TARGET-15-SJMPAL016343 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/11823197-0ad7-4951-993d-0b4278d991e7

Demographics
Sex at birth: female; Age at index: 3 years; Vital status: Dead; Days to death: 511 days (1.4 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 3.3 years (1,198 days); Year of diagnosis: 2000; Days to last follow up: 511 days (1.4 years).

Follow-up (1 entry)
- Days to follow up: 511 days (1.4 years); Event-free: no event (relapse, second malignancy or death) recorded through day 511; Year of follow up: 2001.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 2.7 ×10³/µL.

Biospecimens (8 samples)
- Samples TARGET-15-SJMPAL016343-04A, TARGET-15-SJMPAL016343-04A.1, TARGET-15-SJMPAL016343-04A.2 (3 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Samples TARGET-15-SJMPAL016343-09A, TARGET-15-SJMPAL016343-09A.1, TARGET-15-SJMPAL016343-09A.2, TARGET-15-SJMPAL016343-09A.3 (4 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL016343-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 511
- Protocol: St. Jude
- WBC at Diagnosis: 2.7
- Initial Therapy: AML
- Karyotype: 45,XX,t(8;12)(q13;p12-13),der(15)ins(15;17)(q15;q21q21),-17[7]/46,XX[14]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
- WHO RL1: T/M
